Somatic mutation profile of tumor specimen TCGA-R5-A7ZR-01A (aliquot TCGA-R5-A7ZR-01A-11D-A34U-08) from TCGA case TCGA-R5-A7ZR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 70.6 years (25,795 days).
Specimen TCGA-R5-A7ZR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1095ae2-9387-4c0d-a675-a37114f2f344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R5-A7ZR-10A (Blood Derived Normal), aliquot TCGA-R5-A7ZR-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe914a1a-a6ab-498a-bd5b-2899357b5fbf

The open-access MAF lists 74 somatic variants for this specimen: 55 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 18, Nonsense Mutation 6, 3'UTR 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFIB | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as rs1554709792, COSV101100265, COSV66620419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371425346; called by muse, mutect2, varscan2
- ADGRG4 | c.2903C>G p.A968G | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99795042; called by muse, mutect2, varscan2
- ADI1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs961401919, COSV100537733; called by muse, mutect2, varscan2
- ADRB3 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100799827; called by muse, mutect2, varscan2
- B4GALNT4 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs774400785, COSV57322543; called by muse, mutect2, varscan2
- BCLAF1 | c.2258C>A p.S753Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs138813975, COSV50357270; called by mutect2, varscan2
- CCDC7 | c.3502C>G p.Q1168E | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); catalogued as rs1322895505, COSV100177965; called by muse, mutect2, varscan2
- CDO1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99164771; called by muse, mutect2, varscan2
- CSPP1 | c.382G>A p.A128T (on ENST00000676605; = p.A87T on NM_024790.6) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV99138269; called by muse, mutect2, varscan2
- CYFIP1 | c.3496G>A p.V1166I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs182057951; called by muse, mutect2, varscan2
- DCHS1 | c.6669C>A p.D2223E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1277486635, COSV100201868; called by muse, mutect2, varscan2
- DPP10 | c.522A>C p.E174D | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100062068; called by muse, mutect2, varscan2
- EEF1AKNMT | c.292A>G p.M98V (on ENST00000361735 / NM_015935.5; = p.M12V on NM_014955.3) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1057388566, COSV100675818; called by muse, mutect2, varscan2
- FAT2 | c.10879C>A p.L3627M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV55821639; called by muse, mutect2, varscan2
- GABRE | c.822C>A p.S274R | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100944247; called by muse, mutect2, varscan2
- H3C11 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV100137812; called by muse, mutect2, varscan2
- HSPH1 | c.1229C>G p.S410* | Nonsense Mutation (SNP) | VAF 16/143 reads (11%) | catalogued as COSV100184812; called by muse, varscan2
- HTR5A | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as rs770383539, COSV55281263; called by muse, mutect2, varscan2
- HUWE1 | c.3028G>C p.E1010Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as COSV99471477; called by muse, mutect2
- ITPR2 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as COSV101189921; called by muse, mutect2, varscan2
- KRTAP19-3 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.429); catalogued as COSV61854545; called by muse, mutect2, varscan2
- MAP1B | c.3455C>T p.T1152M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs749214681, COSV57096723; called by muse, mutect2, varscan2
- MAP2K7 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67607651; called by muse, mutect2, varscan2
- MUC16 | c.20072C>A p.T6691K | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as COSV101199288; called by muse, mutect2, varscan2
- NOX1 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV99471527; called by muse, mutect2, varscan2
- NRG1 | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99828172, COSV99829072; called by muse, mutect2, varscan2
- OBSL1 | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1307059037, COSV54705648; called by muse, mutect2, varscan2
- OR13C4 | c.748A>T p.I250L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.037); catalogued as COSV99470085, COSV99470246; called by muse, mutect2, varscan2
- OR52A5 | c.14A>C p.N5T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100263359, COSV99048640; called by muse, mutect2, varscan2
- PAK5 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.033); catalogued as rs559720359, COSV62032667, COSV62039060; called by muse, mutect2, varscan2
- PRSS23 | c.23T>A p.L8H | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV99722331; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1412G>T p.R471I | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100741126; called by muse, mutect2, varscan2
- RHEB | c.554G>T p.*185Lext*6 | Nonstop Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100062037; called by muse, mutect2, varscan2
- RPL24 | c.151T>C p.W51R | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101231170; called by muse, mutect2, varscan2
- SH2B3 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762026350, CM1514124, COSV100374163; called by muse, mutect2, varscan2
- SLC11A1 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99262021; called by muse, mutect2, varscan2
- SLCO1A2 | c.1130T>C p.M377T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1334574515, COSV100261593; called by muse, mutect2, varscan2
- SLCO1C1 | c.1933C>A p.L645I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV99858826; called by muse, mutect2, varscan2
- SORCS3 | c.1969G>A p.G657R | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375044945; called by muse, mutect2, varscan2
- SPINK5 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs552548594, COSV99806448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPRY4 | c.364G>A p.D122N (on ENST00000434127 / NM_001127496.3; = p.D145N on NM_030964.4) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100702162; called by muse, mutect2, varscan2
- SPTBN2 | c.4627C>T p.R1543W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs779489841, COSV100018828; called by muse, mutect2, varscan2
- SYNE1 | c.11727A>G p.I3909M (on ENST00000367255 / NM_182961.4; = p.I3894M on NM_033071.3) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs367946740, COSV99558980; called by muse, mutect2, varscan2
- TIMM8B | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99736031; called by muse, mutect2, varscan2
- TMPRSS15 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as rs771190392, COSV99517493; called by muse, mutect2, varscan2
- VSIG8 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs764729595, COSV100928775; called by muse, mutect2, varscan2
- VTI1B | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.353); catalogued as rs766298691, COSV99373703; called by muse, mutect2, varscan2
- WDR7 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760662291, COSV99589122; called by muse, mutect2, varscan2
- WWC1 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs141513893; called by muse, mutect2, varscan2
- ZNF182 | c.1548T>A p.C516* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100526984; called by muse, mutect2, varscan2
- ZNF296 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs142135795; called by muse, mutect2, varscan2
- ZNF875 | c.1388A>G p.H463R | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100183205; called by muse, mutect2, varscan2
- DCAF1 | c.1572G>C p.L524F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- RREB1 | c.540dup p.E181Rfs*9 | Frame Shift Ins (INS) | VAF 42/125 reads (34%) | called by mutect2, pindel, varscan2
- AEN | c.687G>A p.R229= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs1476407084, COSV100237377; called by muse, mutect2
- ALKBH5 | c.672T>A p.S224= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV101213252; called by muse, mutect2, varscan2
- BLZF1 | c.774T>C p.R258= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100250571; called by muse, mutect2, varscan2
- CAMTA1 | c.1578C>T p.T526= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs989899397, COSV100348092; called by muse, mutect2, varscan2
- CCDC189 | c.381G>A p.A127= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs540907841, COSV100079512, COSV60313950; called by muse, mutect2, varscan2
- EDAR | c.330C>T p.D110= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs372432087; called by muse, mutect2, varscan2
- FABP1 | c.123C>T p.I41= | Silent (SNP) | VAF 144/359 reads (40%) | catalogued as rs745969396, COSV55557901; called by muse, mutect2, varscan2
- FAM24A | c.147T>G p.A49= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV100925074; called by muse, mutect2, varscan2
- GFPT2 | c.708G>A p.K236= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99517531; called by muse, mutect2, varscan2
- OR6C4 | c.702G>A p.K234= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as rs774261067, COSV101263141; called by muse, mutect2, varscan2
- OR6K2 | c.750G>A p.S250= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs372572525, COSV62743177, COSV62743965; called by muse, mutect2, varscan2
- PHLPP1 | c.3630C>T p.D1210= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs367669597; called by muse, mutect2, varscan2
- PREB | c.1140G>T p.L380= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as COSV99574402; called by muse, mutect2, varscan2
- RNF10 | c.414C>T p.I138= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV100378575; called by muse, mutect2, varscan2
- SALL3 | c.3864G>A p.T1288= | Silent (SNP) | VAF 82/231 reads (35%) | catalogued as rs372422021, COSV101609955; called by muse, mutect2, varscan2
- SLC4A1AP | c.1294T>C p.L432= | Silent (SNP) | VAF 74/223 reads (33%) | catalogued as COSV58137648; called by muse, mutect2, varscan2
- ST3GAL2 | c.579C>T p.S193= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100735632; called by muse, mutect2, varscan2
- XYLT2 | c.1497C>T p.P499= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV99190831; called by muse, mutect2, varscan2
- TAFA4 | c.*2G>A | 3'UTR (SNP) | VAF 37/107 reads (35%) | catalogued as rs369406426, COSV55148391; called by muse, mutect2, varscan2
